CCDI case PBCAUJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/957c3307-2c4c-4fa6-8111-848b4e43e008

Demographics
Sex at birth: female.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 8.0 years (2,926 days).

Biospecimens (3 samples)
- Sample 0DMN1G: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMN1X: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMN2E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
